Somatic mutation profile of tumor specimen TCGA-FZ-5926-01A (aliquot TCGA-FZ-5926-01A-11D-1609-08) from TCGA case TCGA-FZ-5926, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.6 years (26,881 days).
Specimen TCGA-FZ-5926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8580fbb1-9cff-4c06-9602-dc5b9cf12b3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5926-11A (Solid Tissue Normal), aliquot TCGA-FZ-5926-11A-01D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94e7178e-f166-47fd-ad7f-141ae9aa6640

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, Nonsense Mutation 4, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/164 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANO3 | c.1506C>A p.D502E | Missense Mutation (SNP) | VAF 26/545 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99884296; called by muse, mutect2
- AP2B1 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 49/667 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV99251463; called by muse, mutect2
- COL5A1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs781248560, COSV65664466; ClinVar: uncertain significance; called by muse, mutect2
- CPEB1 | c.685C>T p.R229C (on ENST00000617958; = p.R169C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs762664847, COSV55618480; called by muse, mutect2
- FBN3 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 22/328 reads (7%) | catalogued as COSV99561443; called by muse, mutect2
- FOCAD | c.1402C>T p.L468F | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100620590; called by muse, mutect2
- HFM1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 10/311 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99646400; called by muse, mutect2
- KCNJ2 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99696451; called by muse, mutect2
- KDM6A | c.2764A>T p.R922* | Nonsense Mutation (SNP) | VAF 26/526 reads (5%) | catalogued as COSV100938442; called by muse, mutect2
- MEFV | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs144998416; called by muse, mutect2
- NLRP10 | c.1854T>A p.C618* | Nonsense Mutation (SNP) | VAF 14/370 reads (4%) | catalogued as COSV100149853; called by muse, mutect2
- NONO | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 36/622 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV99339020; called by muse, mutect2
- QKI | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs904511733, COSV51691951, COSV51697910; called by muse, mutect2
- RNF213 | c.9092G>A p.G3031D | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV100301151; called by muse, mutect2
- SGK2 | c.540+1G>T p.X180_splice | Splice Site (SNP) | VAF 26/367 reads (7%) | catalogued as COSV100414767, COSV58315796; called by muse, mutect2
- TTN | c.28976G>A p.G9659D (on ENST00000591111; = p.G8732D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/204 reads (4%) | PolyPhen probably damaging (1); catalogued as rs1183241604, COSV100622110; called by muse, mutect2
- UBR4 | c.8965C>T p.R2989* | Nonsense Mutation (SNP) | VAF 24/548 reads (4%) | catalogued as COSV64389325; called by muse, mutect2
- ULK4 | c.3380G>T p.R1127L | Missense Mutation (SNP) | VAF 35/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs374410332, COSV100094100; called by muse, mutect2
- ALOX15B | c.291G>A p.P97= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101205663; called by muse, mutect2
- CSMD2 | c.1920C>T p.A640= | Silent (SNP) | VAF 36/502 reads (7%) | catalogued as rs547519483, COSV53933154; called by muse, mutect2
- JHY | c.1587C>T p.L529= | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as COSV99913526; called by muse, mutect2
- MMEL1 | c.1161C>T p.I387= | Silent (SNP) | VAF 30/388 reads (8%) | catalogued as rs368809746; called by muse, mutect2
- MMP9 | c.1398G>A p.T466= | Silent (SNP) | VAF 51/592 reads (9%) | catalogued as COSV63434414; called by muse, mutect2
- NR2F1 | c.603G>A p.S201= | Silent (SNP) | VAF 18/461 reads (4%) | catalogued as COSV59068453; called by muse, mutect2
- REM1 | c.102C>T p.S34= | Silent (SNP) | VAF 40/426 reads (9%) | catalogued as COSV52428347, COSV99147495; called by muse, mutect2
- TASOR | c.3645G>A p.L1215= (on ENST00000355628 / NM_001365636.2; = p.L839= on NM_015224.3) | Silent (SNP) | VAF 19/230 reads (8%) | catalogued as COSV100843662; called by muse, mutect2
- UBA1 | c.408T>C p.A136= | Silent (SNP) | VAF 18/577 reads (3%) | catalogued as COSV100255927; called by muse, mutect2
- HOXD4 | chr2:176150360 G>A | 5'Flank (SNP) | VAF 33/425 reads (8%) | catalogued as rs1457349764; called by muse, mutect2
